Somatic mutation profile of tumor specimen TARGET-10-PANXEE-09A (aliquot TARGET-10-PANXEE-09A-01D) from TARGET case TARGET-10-PANXEE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (941 days).
Specimen TARGET-10-PANXEE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d8ecb47-f1cd-4f5a-9470-80d8e27c593a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANXEE-10A (Blood Derived Normal), aliquot TARGET-10-PANXEE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/749a78fc-5fdf-4bb0-880e-330a88176333

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IL13RA2 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs782365549; called by muse, mutect2, varscan2
- MAP3K3 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs77866388, COSV51991717; called by muse, mutect2, varscan2
- REEP2 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750508403, COSV54735176; called by mutect2, varscan2
- DNAH5 | c.2464G>T p.D822Y | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POM121 | chr7:72949980 G>C | 3'Flank (SNP) | VAF 5/32 reads (16%) | catalogued as rs782420332; called by muse, mutect2, varscan2
- YY1AP1 | c.48-108C>G | Intron (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
